Gene-level copy-number profile of tumor specimen HTMCP-03-06-02085-01B from CGCI case HTMCP-03-06-02085, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02085-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 704f3b08-c9d4-44bb-a299-e89caca8b2a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02085-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/1a594794-8d90-4b95-b7b3-c7c2c04a7dbd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 124; copy number 2: 1,883; copy number 3: 741; copy number 4: 31,130; copy number 5: 1,056; copy number 6: 18,494; copy number 7: 844; copy number 8: 2,694; copy number 9: 459; copy number 10: 402; copy number 11: 215; copy number 12: 148; copy number 13: 75; copy number 14: 17; copy number 15: 37; copy number 16: 4; copy number 19: 28.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,700,151–149,700,296, 1 gene (within-gene range 0–2): RNU1-68P.
- chr2:130,082,092–130,082,220, 1 gene (within-gene range 0–5): AC018865.1.
- chr3:11,745–409,417, 7 genes (within-gene range 0–4): LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1.
- chr16:16,260,866–16,261,235, 1 gene (within-gene range 0–4): AC136624.3.
- chr16:68,450,283–68,835,541, 15 genes (within-gene range 0–4): AC099521.1, Y_RNA, RPL35AP33, ZFP90, RNU4-36P, AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429.
- chr17:19,600,860–19,633,825, 7 genes: AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,385 genes in 56 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:960,584–1,179,555, 21 genes, copy number 11 (within-gene range 5–11): KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1.
- chr1:30,810,378–31,239,887, 12 genes, copy number 10: AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1.
- chr1:109,548,615–109,652,099, 8 genes, copy number 9: GNAI3, RNU6V, AL355310.1, MIR197, GNAT2, AMPD2, AL355310.2, RPL7P8.
- chr1:150,600,539–150,629,612, 3 genes, copy number 9: AL356356.1, ENSA, U4.
- chr1:179,025,804–179,691,272, 22 genes, copy number 10: FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5.
- chr1:200,623,896–201,829,559, 33 genes, copy number 10–14 (within-gene range 6–14): DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P.
- chr1:223,779,893–225,399,292, 31 genes, copy number 9–10: TP53BP2, PHBP11, ACTBP11, CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4, WDR26, MIR4742, CNIH3, AKR1B1P1, CNIH3-AS2, DNAJB6P6, AL596330.1, CNIH3-AS1, LINC02813, DNAH14.
- chr2:38,406,527–38,741,237, 9 genes, copy number 9–16: LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2, HNRNPLL, AC011247.1, GALM, AC074366.1.
- chr2:62,168,862–62,491,468, 7 genes, copy number 10: AC018462.2, B3GNT2, MIR5192, RN7SL51P, AC093159.2, AC093159.1, RN7SL18P.
- chr2:66,574,030–69,674,349, 52 genes, copy number 10 (within-gene range 6–10): LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1, AC015969.1, PLEK, AC127383.1, FBXO48, APLF, AC130709.1, PROKR1, ARHGAP25, LINC01890, LINC01888, BMP10, GKN2, GKN1, ANTXR1, AC114802.1, MIR3126, RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1, AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1.
- chr2:83,522,814–85,905,199, 61 genes, copy number 9–19 (broad region; genes not listed).
- chr2:119,366,921–121,310,412, 34 genes, copy number 9: DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7.
- chr2:163,288,995–164,843,679, 10 genes, copy number 9: RNU6-627P, FIGN, AC016766.1, PRPS1P1, CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr3:96,566,357–103,241,230, 113 genes, copy number 9–12 (broad region; genes not listed).
- chr3:121,567,949–123,992,178, 45 genes, copy number 13: ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, CASR, HNRNPA1P23, CSTA, CCDC58, FAM162A, WDR5B, AC083798.2, AC083798.1, KPNA1, AC096861.1, PARP9, DTX3L, PARP15, EIF4BP8, PARP14, HSPBAP1, SLC49A4, LINC02035, SEMA5B, PDIA5, MIR7110, SEC22A, AC112503.2, ADCY5, AC112503.1, HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1.
- chr3:158,732,198–159,897,366, 14 genes, copy number 12 (within-gene range 8–12): MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1, IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1.
- chr3:192,796,815–195,913,986, 83 genes, copy number 12 (broad region; genes not listed).
- chr4:1,289,887–2,418,651, 32 genes, copy number 9: MAEA, UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1.
- chr5:66,507,380–67,806,600, 11 genes, copy number 9–10 (within-gene range 8–10): LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1, MAST4-AS1, CD180, AC010420.1, AC112206.2, AC079467.1, AC112206.1.
- chr6:29,708,125–30,470,251, 68 genes, copy number 9 (broad region; genes not listed).
- chr6:35,342,558–35,512,896, 7 genes, copy number 10: PPARD, MKRN6P, FANCE, RPL10A, MIR7111, TEAD3, TULP1.
- chr6:54,770,583–56,394,094, 12 genes, copy number 10 (within-gene range 6–10): KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1.
- chr6:76,521,640–79,575,530, 28 genes, copy number 10–14: LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.2, AL451064.1, AL451064.2.
- chr7:101,205,977–101,321,823, 10 genes, copy number 9: PLOD3, ZNHIT1, CLDN15, FIS1, RNU6-1104P, AC006329.1, AZGP1P2, LNCPRESS1, EMSLR, IFT22.
- chr9:21,278,050–23,438,700, 42 genes, copy number 9: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:5,498,697–6,062,370, 21 genes, copy number 10–13: CALML5, CALML3-AS1, CALML3, AL732437.1, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1.
- chr11:71,453,109–74,009,085, 115 genes, copy number 11 (broad region; genes not listed).
- chr11:76,349,956–78,582,156, 64 genes, copy number 10 (broad region; genes not listed).
- chr11:101,129,077–103,895,271, 55 genes, copy number 9 (within-gene range 6–9): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1.
- chr11:129,537,869–129,617,269, 3 genes, copy number 11: RPS27P20, AP003500.1, LINC01395.
- chr12:40,978,744–42,590,355, 24 genes, copy number 10: AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr14:21,997,539–22,505,167, 70 genes, copy number 10 (broad region; genes not listed).
- chr14:67,189,393–67,816,590, 30 genes, copy number 10: FAM71D, SF3B4P1, MPP5, AL135978.1, ATP6V1D, Y_RNA, EIF2S1, PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.
- chr14:104,376,530–105,181,323, 37 genes, copy number 15: AL512357.1, RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1, AL583722.2, LINC02280, MIR4710, INF2, AL583722.3, ADSS1, SIVA1, AL583722.1, AKT1, ZBTB42, AL590326.1, LINC00638, RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2, CLBA1, CDCA4, GPR132, LINC02298, AL512356.4, AL512356.3, AL512356.2, JAG2, MIR6765, AL512356.1, NUDT14.
- chr16:28,379,579–28,415,018, 3 genes, copy number 12: EIF3CL, MIR6862-1, CDC37P2.
- chr16:70,246,778–70,801,160, 27 genes, copy number 9: EXOSC6, AARS1, RN7SL279P, DDX19B, AC012184.2, AC012184.3, DDX19A, AC012184.4, ST3GAL2, AC012184.1, RPS27P26, RNU6-23P, FCSK, COG4, SF3B3, SNORD111B, SNORD111, IL34, MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1, VAC14-AS1, AC020763.5, AC020763.2, AC027281.1.
- chr17:54,702,936–55,872,939, 19 genes, copy number 12: AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1.
- chr19:44,631,573–45,038,198, 26 genes, copy number 9 (within-gene range 6–9): AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB.
- chr20:46,364,551–47,188,844, 21 genes, copy number 10: AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616.
- chr20:63,127,495–64,327,972, 76 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 124. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
